HCMI case HCM-CSHL-0803-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/3e296517-6c60-4f65-ab54-98b1753ed39c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Days to birth: -23,448 days (64.2 years before the index date); Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Carcinosarcoma, NOS: ICD-O-3 morphology code: 8980/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No; Peritoneal fluid cytological status: Non-Malignant.
   Pathology details: Additional pathology findings: Adenomyosis; Lymph node involvement: Negative; Lymphatic invasion present: No; Tumor largest dimension diameter: 9 cm; Vascular invasion present: No.
   Pathology details: Additional pathology findings: Endometrial polyp.
   Pathology details: Additional pathology findings: Bilateral ovaries with endometriotic cyst and surface adhesions.
   Pathology details: Additional pathology findings: Leiomyomata w/ degenerative changes.
   Pathology details: Additional pathology findings: Benign endocervical polyp.
   Pathology details: Additional pathology findings: Atrophic endometrium.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 53 days; Days to treatment end: 156 days.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 197 days; Days to treatment end: 206 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 513 days (1.4 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 273.

Molecular and laboratory tests
- MLH1 (IHC): Negative.
- MLH1 hypermethylation: Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 100.2 kg; Height: 167.9 cm; BMI: 35.
- Timepoint category: Prior to Diagnosis; Comorbidities: Cancer / Hypertension; Risk factors: Cancer / Hypertension / Adenomyosis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0803-C54-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0803-C54-11A-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 80; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 7.
- Sample HCM-CSHL-0803-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
